Somatic mutation profile of tumor specimen TCGA-QR-A6GT-01A (aliquot TCGA-QR-A6GT-01A-11D-A35D-08) from TCGA case TCGA-QR-A6GT, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 63.5 years (23,208 days).
Specimen TCGA-QR-A6GT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e86b68c-d23b-4345-875e-62de18788ed8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6GT-10A (Blood Derived Normal), aliquot TCGA-QR-A6GT-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcf23d49-b5f3-4af0-94c4-9731f042a242

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Frame Shift Del 2, Nonsense Mutation 2, Nonstop Mutation 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F13A1 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs142954620, COSV99342345; called by muse, mutect2, varscan2
- PHTF2 | c.25A>G p.I9V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as rs778356622, COSV50333400; called by muse, mutect2, varscan2
- PRRC2C | c.1403G>A p.R468H (on ENST00000367742; = p.R466H on NM_015172.4) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1382937382; called by muse, mutect2, varscan2
- RPS27A | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs575180825; called by muse, varscan2
- RRBP1 | c.2482C>T p.R828W (on ENST00000377813 / NM_001365613.2; = p.R395W on NM_004587.3) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261503459; called by muse, mutect2, varscan2
- SUPT16H | c.2633C>T p.S878F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.933); catalogued as COSV99359708; called by muse, mutect2, varscan2
- TUB | c.55G>A p.G19S (on ENST00000299506 / NM_177972.3; = p.G74S on NM_003320.4) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0.012); catalogued as rs1201147989; called by muse, mutect2, varscan2
- UNC5A | c.1589G>T p.S530I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs1471178136; called by muse, mutect2, varscan2
- ATP2A1 | c.1494C>A p.C498* | Nonsense Mutation (SNP) | VAF 38/113 reads (34%) | called by muse, mutect2, varscan2
- ATRX | c.1485del p.K495Nfs*19 | Frame Shift Del (DEL) | VAF 99/297 reads (33%) | called by mutect2, pindel, varscan2
- CCDC171 | c.40A>G p.R14G | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2
- DSC2 | c.212T>G p.F71C | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM122C | c.189G>A p.L63= | Splice Region (SNP) | VAF 46/83 reads (55%) | called by muse, mutect2, varscan2
- KAT6A | c.1775A>T p.N592I | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MAGEB1 | c.64A>T p.T22S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- MRGPRX3 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- NEK4 | c.2297C>T p.S766L | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by mutect2, varscan2
- NIBAN1 | c.2188A>C p.M730L | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- PNO1 | c.661del p.A221Qfs*8 | Frame Shift Del (DEL) | VAF 28/97 reads (29%) | called by mutect2, pindel, varscan2
- RABEPK | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.522); called by muse, mutect2
- RBP2 | c.401_*6del | Nonstop Mutation (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- SRP72 | c.990A>T p.L330F | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- ZZEF1 | c.2313C>G p.F771L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BZW2 | c.780G>A p.K260= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- INSRR | c.2043C>T p.A681= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs1240402189; called by muse, mutect2, varscan2
- IPPK | c.150A>G p.Q50= | Silent (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- PPT2 | c.855C>T p.A285= | Silent (SNP) | VAF 52/200 reads (26%) | called by muse, mutect2, varscan2
- XPNPEP2 | c.1101C>T p.A367= | Silent (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- ZNF407 | c.5571G>A p.A1857= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs760134393, COSV55262370; called by muse, mutect2, varscan2
- GTF2H2B | n.858A>G | RNA (SNP) | VAF 7/74 reads (9%) | called by mutect2, varscan2
